Gene-level copy-number profile of tumor specimen TCGA-WE-A8K1-06A from TCGA case TCGA-WE-A8K1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Superficial spreading melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.2 years (28,197 days).
Specimen TCGA-WE-A8K1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.db6fb307-83a1-45fb-bf30-82945e401cf3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WE-A8K1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7e003674-4ce2-40e2-9f43-746fb2c78e19

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 7,765; copy number 2: 43,335; copy number 3: 6,893; copy number 4: 1,587; copy number 5: 95; copy number 6: 9; copy number 7: 45; copy number 10: 31; copy number 12: 24; copy number 14: 22; copy number 15: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WE-A8K1-06A-21D-A371-01): tumor purity 0.44, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:158,730,995–159,233,377, 7 genes (within-gene range 0–1): ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 163 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:66,780,076–69,593,121, 29 genes, copy number 5: AC098969.2, AC098969.1, AC020655.1, KBTBD8, MIR4272, AC114401.1, SUCLG2, NDUFB4P1, SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1.
- chr3:69,769,487–69,769,773, 1 gene, copy number 5: RN7SL418P.
- chr11:57,917,297–57,946,414, 2 genes, copy number 12: OR5AZ1P, OR5BD1P.
- chr11:69,641,156–70,207,390, 18 genes, copy number 12–15: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1.
- chr19:14,863,714–15,332,545, 22 genes, copy number 14 (within-gene range 1–14): OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4.
- chr19:16,015,287–16,660,115, 43 genes, copy number 7 (within-gene range 1–7): LINC00661, AC004790.2, LINC00905, SNX33P1, AC004790.1, OR1AB1P, LINC01855, TPM4, AC008894.3, AC008894.1, RAB8A, AC008894.2, HSH2D, CIB3, FAM32A, AC020911.1, Metazoa_SRP, AC020911.3, AP1M1, AC020911.2, KLF2, AC020917.3, EPS15L1, AC020917.4, AC020917.1, AC020917.2, CALR3, AC008764.1, C19orf44, CHERP, RN7SL146P, AC008764.6, SLC35E1, AC008764.3, AC008764.5, AC008764.8, MED26, AC008764.4, AC008764.7, AC008764.9, AC008764.10, AC008764.2, AC024075.3.
- chr19:16,633,797–16,640,668, 2 genes, copy number 7: AC024075.2, AC024075.1.
- chr19:17,390,509–18,098,944, 40 genes, copy number 6–10: CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS, AC010618.2, NIBAN3, COLGALT1, AC010618.1, UNC13A, AC008761.2, AC008761.3, MAP1S, AC008761.1, FCHO1, B3GNT3, INSL3, JAK3, RPL18A, SNORA68, AC005796.1, SLC5A5, CCDC124, KCNN1, RNA5SP468, ARRDC2, AC020904.3, AC020904.2, AC020904.1, RPS18P13, IL12RB1.
- chr19:21,496,682–21,594,628, 6 genes, copy number 12: ZNF429, BNIP3P26, AC123912.1, AC123912.4, AC123912.2, AC123912.6.

Autosomal genes at a single copy (total copy number 1): 6,111. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
